Somatic mutation profile of tumor specimen TCGA-AP-A1E0-01A (aliquot TCGA-AP-A1E0-01A-11D-A135-09) from TCGA case TCGA-AP-A1E0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 40.1 years (14,653 days).
Specimen TCGA-AP-A1E0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8329150d-5560-47eb-93f9-cbc0afac9450.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1E0-10A (Blood Derived Normal), aliquot TCGA-AP-A1E0-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e807781-7d03-4a61-9a68-cdea87270f41

The open-access MAF lists 5,496 somatic variants for this specimen: 4,344 protein-altering or splice-affecting, 1,025 silent, 127 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,705, Silent 1,025, Nonsense Mutation 539, Splice Site 65, Intron 48, RNA 39, Splice Region 17, 5'Flank 12, 3'UTR 11, 3'Flank 9, 5'UTR 8, Frame Shift Del 6.

Variants (750 of 5,496; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs63750427, CM001040, CM030399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.3682C>T p.R1228* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as rs113994131, CM960018, COSV54049415, COSV99649605; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ALMS1 | c.6433C>T p.R2145* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as rs770558150, CM152829, COSV52514260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3602C>A p.S1201* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as rs730881247, CD106445, CM010755, COSV57324987, COSV57362864; ClinVar: likely pathogenic; called by muse, mutect2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP8A2 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs1064795610, COSV54981282; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- BRCA2 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as rs587782014, COSV101204327; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHRND | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375623674, CM124431; ClinVar: likely pathogenic; called by mutect2, varscan2
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.4880G>A p.R1627Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs767331775, COSV71672487; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307547, COSV74205114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.11944C>T p.R3982* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs1555188379, CM111920, COSV56450787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MYL2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs104894368, CM961005, COSV57405974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NEXN | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs971313210, COSV57358805; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGN | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1382897257, COSV100715935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs398123324, COSV100910708, COSV64297317, COSV64299553; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- PTEN | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122894, COSV64288557, COSV64309376; called by muse, mutect2, varscan2
- RASA1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs1463885690, CM083070, COSV57192389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs727503396, COSV63664819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.7160C>T p.A2387V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs794728754, CM133736, COSV100770994; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHOX | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852556, CM011486, COSV61862044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC9A6 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 37/89 reads (42%) | catalogued as rs122461162, CM081439, COSV65787941; ClinVar: pathogenic; called by muse, varscan2
- TRAPPC6B | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as rs377626365; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.85447G>T p.E28483* (on ENST00000591111; = p.E21059* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1553539995, COSV59918596, COSV60071705; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TYRP1 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as rs121912778, CM052392, COSV66357901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.5329C>T p.R1777W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); catalogued as rs770329105, CM115978, COSV56356498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3521C>A p.A1174D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100588746; called by muse, mutect2, varscan2
- A2ML1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs758305694, COSV100229195, COSV55290676; called by muse, mutect2, varscan2
- AADACL2 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV62931402; called by muse, mutect2
- AAK1 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.885); catalogued as rs759128042, COSV101275977; called by muse, varscan2
- AARS1 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99933559; called by muse, mutect2, varscan2
- AASDH | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs765349701, COSV52704659; called by muse, mutect2, varscan2
- ABCA1 | c.5702G>T p.R1901I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV66064710; called by muse, mutect2, varscan2
- ABCA12 | c.5362G>A p.E1788K (on ENST00000272895 / NM_173076.3; = p.E1470K on NM_015657.3) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.118); catalogued as rs758326051, COSV99789601; called by muse, mutect2, varscan2
- ABCA12 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.061); catalogued as rs773100250, COSV55953508; called by muse, mutect2, varscan2
- ABCA13 | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV70034370; called by muse, mutect2, varscan2
- ABCA4 | c.2796G>T p.K932N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs775951957, COSV64673378; called by muse, varscan2
- ABCA4 | c.1748A>T p.K583M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM1513465, COSV100933148; called by muse, mutect2, varscan2
- ABCA8 | c.2360C>A p.S787* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99286070; called by muse, mutect2, varscan2
- ABCA9 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as rs1386994010, COSV60623882; called by muse, mutect2, varscan2
- ABCA9 | c.2147A>C p.H716P | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100383193; called by muse, mutect2, varscan2
- ABCB1 | c.2064+1G>A p.X688_splice | Splice Site (SNP) | VAF 23/55 reads (42%) | catalogued as COSV99713295; called by muse, mutect2, varscan2
- ABCB1 | c.1182C>A p.F394L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99713296; called by muse, mutect2, varscan2
- ABCB1 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55959158, COSV99713297; called by muse, mutect2, varscan2
- ABCB11 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV99792369; called by muse, mutect2
- ABCB4 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99709891; called by mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCC11 | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100750852; called by muse, mutect2
- ABCC12 | c.3996G>T p.V1332= | Splice Region (SNP) | VAF 26/51 reads (51%) | catalogued as rs540503825, COSV100252807; called by muse, mutect2, varscan2
- ABCC12 | c.2744A>G p.D915G | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312066829, COSV100252808; called by muse, mutect2, varscan2
- ABCC2 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs756825916, COSV64985495; called by muse, varscan2
- ABCC4 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV100972555; called by muse, mutect2, varscan2
- ABCD1 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.498); catalogued as COSV99497659, COSV99497814; called by muse, mutect2, varscan2
- ABCE1 | c.1219C>A p.L407I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV56848312, COSV99668637; called by muse, mutect2, varscan2
- ABCG1 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs750249283, CM120301, COSV100494269; called by muse, mutect2, varscan2
- ABCG2 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs761288842, COSV52949203; called by muse, mutect2, varscan2
- ABHD18 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101180766; called by muse, mutect2, varscan2
- ABHD18 | c.1022C>A p.S341Y (on ENST00000398965 / NM_001039717.2; = p.S248Y on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101180768; called by muse, mutect2, varscan2
- ABHD5 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV50006356; called by muse, mutect2, varscan2
- ABI2 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99651880; called by mutect2, varscan2
- ABLIM2 | c.1681C>T p.R561C (on ENST00000341937 / NM_001130084.2; = p.R471C on NM_032432.5) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755982683, COSV56404836; called by muse, mutect2, varscan2
- ABLIM2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779636454, COSV56406103; called by muse, mutect2, varscan2
- ABTB2 | c.2910C>A p.F970L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100131507; called by muse, mutect2, varscan2
- ABTB2 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs903641747, COSV100131510; called by muse, mutect2, varscan2
- AC005833.1 | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious, low confidence (0); catalogued as COSV99362906; called by muse, mutect2
- AC005833.1 | c.1523G>T p.R508I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); catalogued as COSV99362907; called by muse, mutect2, varscan2
- AC098582.1 | c.2014G>T p.G672* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99985680; called by muse, mutect2, varscan2
- AC098582.1 | c.2740C>A p.L914I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99985686; called by muse, mutect2, varscan2
- AC136428.1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs766270124, COSV101434973; called by muse, mutect2, varscan2
- AC242842.3 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1392428854; called by muse, mutect2, varscan2
- ACAD10 | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100564282; called by muse, mutect2, varscan2
- ACADSB | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV100715104; called by muse, mutect2, varscan2
- ACAP1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV50139460; called by muse, mutect2, varscan2
- ACAP2 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs141761176; called by muse, mutect2, varscan2
- ACAP3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100686262; called by muse, mutect2, varscan2
- ACAT1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99759262; called by muse, mutect2
- ACE2 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as rs773848804, COSV53024902; called by muse, mutect2, varscan2
- ACE2 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs764661406, COSV53024833; called by muse, mutect2, varscan2
- ACO1 | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59378783; called by muse, mutect2, varscan2
- ACOT12 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100296973; called by muse, mutect2, varscan2
- ACOT12 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765750902, COSV100296975; called by muse, mutect2, varscan2
- ACP2 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.269); catalogued as rs865928928, COSV99922177; called by muse, mutect2, varscan2
- ACSBG2 | c.36A>C p.K12N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99397477; called by muse, mutect2, varscan2
- ACSL4 | c.722G>A p.G241E (on ENST00000340800 / NM_022977.2; = p.G200E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100538659; called by mutect2, varscan2
- ACSM1 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs764099827, COSV99533077; called by muse, mutect2, varscan2
- ACTN3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1201348087, COSV101557848; called by muse, mutect2, varscan2
- ACTR3B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs777551709, COSV55453624; called by muse, mutect2, varscan2
- ACTRT1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs767426435, COSV100947568, COSV64419153; called by muse, mutect2, varscan2
- ACVR1 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.24); catalogued as COSV99717851; called by muse, mutect2, varscan2
- ADAD1 | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as rs1027849295, COSV99635792; called by muse, mutect2, varscan2
- ADAD2 | c.1426G>A p.E476K (on ENST00000315906 / NM_001145400.2; = p.E558K on NM_139174.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754189973, COSV51893826; called by muse, mutect2, varscan2
- ADAM11 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99567537; called by muse, mutect2, varscan2
- ADAM2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99697492; called by muse, mutect2, varscan2
- ADAM23 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV52209973; called by muse, mutect2, varscan2
- ADAM23 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.793); catalogued as COSV100007900; called by muse, mutect2, varscan2
- ADAM23 | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100007903; called by muse, mutect2, varscan2
- ADAM28 | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); catalogued as COSV99738878; called by muse, mutect2, varscan2
- ADAMTS1 | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53169558; called by muse, mutect2, varscan2
- ADAMTS12 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100711128, COSV61276639; called by muse, mutect2, varscan2
- ADAMTS18 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51419524; called by muse, mutect2
- ADAMTS7 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751121773, COSV101183094; called by muse, mutect2, varscan2
- ADAMTS9 | c.4941G>T p.E1647D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99899621; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2600G>T p.R867M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV101001944; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4388C>A p.S1463Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV101000500; called by muse, mutect2
- ADAMTSL1 | c.5258C>A p.S1753Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV101000869; called by muse, mutect2, varscan2
- ADAP1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as rs1258238111, COSV99763112; called by muse, mutect2, varscan2
- ADARB2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67240066; called by muse, mutect2, varscan2
- ADCY1 | c.3160C>A p.L1054I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99812218; called by muse, mutect2, varscan2
- ADCY10 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as rs764401962, COSV100896905; called by muse, mutect2, varscan2
- ADCY8 | c.2427T>A p.F809L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99652688; called by muse, mutect2, varscan2
- ADCY9 | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770070508, COSV99570168; called by muse, mutect2, varscan2
- ADCY9 | c.3257A>G p.N1086S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99570171; called by muse, mutect2, varscan2
- ADCY9 | c.1696T>G p.L566V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as rs1358886221, COSV99570175; called by muse, mutect2
- ADGRA1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.038); catalogued as rs754462630, COSV101192711; called by muse, mutect2, varscan2
- ADGRB3 | c.4232C>A p.S1411Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53235619; called by muse, mutect2, varscan2
- ADGRD1 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as COSV99895867; called by muse, mutect2, varscan2
- ADGRE1 | c.2313G>A p.W771* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99165403; called by muse, mutect2, varscan2
- ADGRF1 | c.1436T>G p.I479S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99347340; called by muse, mutect2, varscan2
- ADGRF1 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99347343; called by muse, mutect2, varscan2
- ADGRF1 | c.988C>A p.L330I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99347347; called by muse, mutect2, varscan2
- ADGRG4 | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99795769; called by muse, mutect2, varscan2
- ADGRG4 | c.5098C>A p.L1700I | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV99795772; called by muse, mutect2, varscan2
- ADGRG4 | c.6086T>G p.V2029G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV99795774; called by muse, mutect2, varscan2
- ADGRG4 | c.8623C>A p.L2875M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99795775; called by muse, mutect2, varscan2
- ADGRG4 | c.9158C>A p.S3053Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99793988, COSV99795778; called by muse, mutect2, varscan2
- ADGRG4 | c.9235T>G p.S3079A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV99795779; called by muse, varscan2
- ADGRG6 | c.461G>T p.R154M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99747543; called by muse, mutect2, varscan2
- ADGRG6 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as COSV51600680, COSV99747549; called by muse, mutect2, varscan2
- ADGRL4 | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV100876095; called by muse, mutect2
- ADGRV1 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753590100, COSV101316101, COSV67977917; called by muse, mutect2, varscan2
- ADGRV1 | c.11500G>T p.E3834* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101316102; called by muse, mutect2, varscan2
- ADORA2A | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100418062; called by muse, mutect2, varscan2
- ADPRH | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV100813328, COSV63694808; called by muse, mutect2
- ADSS1 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs778986361, COSV100272304; called by muse, mutect2, varscan2
- ADSS2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100836858; called by muse, mutect2, varscan2
- AFDN | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100653105; called by muse, mutect2, varscan2
- AFF1 | c.3140T>G p.F1047C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100320735; called by muse, mutect2, varscan2
- AFF1 | c.3516C>A p.F1172L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV100320737; called by muse, mutect2, varscan2
- AFF4 | c.3436C>T p.R1146C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755303727, COSV54793041; called by muse, mutect2, varscan2
- AFP | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV56924278, COSV99890056; called by muse, mutect2, varscan2
- AFP | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99890061; called by muse, mutect2, varscan2
- AFP | c.1653-1G>T p.X551_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99890064; called by muse, mutect2, varscan2
- AGAP2 | c.2414G>A p.R805Q (on ENST00000547588 / NM_001122772.2; = p.R469Q on NM_014770.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs149269984; called by muse, mutect2, varscan2
- AGFG2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.515); catalogued as rs189195016, COSV99499377; called by muse, mutect2, varscan2
- AGFG2 | c.929A>C p.Q310P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99499378; called by muse, mutect2, varscan2
- AGL | c.2379G>T p.E793D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99649404; called by muse, mutect2, varscan2
- AGO3 | c.1733T>G p.I578S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV99868807; called by muse, mutect2
- AGO4 | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.764); catalogued as COSV100942986; called by muse, mutect2, varscan2
- AGPAT4 | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV100211577; called by muse, mutect2, varscan2
- AGPAT5 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99576522; called by muse, mutect2
- AGTPBP1 | c.2620C>T p.R874W (on ENST00000357081 / NM_001330701.2; = p.R834W on NM_015239.2) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1418982979, COSV61270623; called by muse, mutect2, varscan2
- AGTPBP1 | c.2357C>T p.S786L (on ENST00000357081 / NM_001330701.2; = p.S746L on NM_015239.2) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1301788639, COSV61270146; called by mutect2, varscan2
- AGTPBP1 | c.1896G>T p.E632D (on ENST00000357081 / NM_001330701.2; = p.E592D on NM_015239.2) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as COSV100429877; called by muse, mutect2, varscan2
- AHCYL2 | c.1143-1G>T p.X381_splice | Splice Site (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100273483; called by muse, mutect2, varscan2
- AHNAK | c.17029G>T p.E5677* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV57227843, COSV99947929; called by mutect2, varscan2
- AHNAK2 | c.8668G>A p.A2890T | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100317850; called by muse, mutect2, varscan2
- AHNAK2 | c.2043G>T p.K681N | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100317625; called by muse, mutect2, varscan2
- AHRR | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs373499533; called by muse, mutect2, varscan2
- AIFM3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs774483526, COSV99301900; called by muse, mutect2, varscan2
- AIPL1 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.739); catalogued as COSV100006087; called by muse, mutect2
- AJM1 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99915721; called by muse, mutect2, varscan2
- AK4 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59198547; called by muse, mutect2, varscan2
- AK5 | c.493G>T p.E165* (on ENST00000354567 / NM_174858.3; = p.E139* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100481295; called by muse, mutect2, varscan2
- AKAP12 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99483603; called by muse, mutect2, varscan2
- AKAP13 | c.5259G>T p.K1753N (on ENST00000394518 / NM_007200.5; = p.K1757N on NM_006738.6) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV63465806; called by muse, mutect2
- AKAP4 | c.1916A>C p.N639T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV100654287; called by muse, mutect2, varscan2
- AKAP4 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100654289; called by muse, mutect2, varscan2
- AKAP4 | c.1144T>G p.L382V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100654290; called by muse, mutect2, varscan2
- AKAP5 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100278001; called by muse, mutect2, varscan2
- AKAP6 | c.2598T>G p.S866R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99801613; called by muse, varscan2
- AKAP6 | c.4609G>T p.D1537Y | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV55219195, COSV99801618; called by muse, mutect2, varscan2
- AKAP8 | c.1328A>C p.K443T | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99511981; called by muse, mutect2, varscan2
- AKAP9 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs864622705, COSV100662522, COSV62344491; called by muse, mutect2, varscan2
- AKAP9 | c.2410A>G p.I804V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs767890689, COSV100662523; called by muse, mutect2, varscan2
- AKAP9 | c.4938A>C p.E1646D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.092); catalogued as COSV100662524; called by muse, mutect2, varscan2
- AKAP9 | c.9008C>A p.P3003H (on ENST00000359028; = p.P2979H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as COSV100662525; called by mutect2, varscan2
- AKAP9 | c.9129C>A p.F3043L (on ENST00000359028; = p.F3019L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100662527, COSV62344994; called by muse, mutect2, varscan2
- AKAP9 | c.11056C>A p.L3686I (on ENST00000359028; = p.L3662I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100662528; called by muse, mutect2, varscan2
- AKNAD1 | c.2367A>T p.E789D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100892560; called by muse, mutect2, varscan2
- AKR1B1 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53648990, COSV99605287; called by muse, mutect2
- AKR1C1 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101080492; called by muse, mutect2, varscan2
- AL136295.1 | c.2283C>A p.F761L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99938106; called by muse, mutect2, varscan2
- AL136295.1 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV99841760; called by muse, mutect2, varscan2
- AL645922.1 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs763450579, COSV54962560; called by muse, mutect2, varscan2
- ALB | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as rs1459896687, COSV99891621; called by muse, mutect2
- ALDH1B1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs770780314, COSV66620189; called by muse, varscan2
- ALDH1L1 | c.2355C>A p.F785L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99856987; called by muse, mutect2, varscan2
- ALDH1L2 | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99311110; called by muse, mutect2, varscan2
- ALDH1L2 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs749336065, COSV99311113; called by muse, mutect2, varscan2
- ALDH3A1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855942; called by muse, mutect2, varscan2
- ALDH6A1 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV63246311; called by muse, mutect2, varscan2
- ALDOB | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100878883, COSV66397835; called by muse, mutect2, varscan2
- ALG13 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV52644769; called by muse, mutect2, varscan2
- ALG13 | c.1775A>C p.K592T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99322441; called by muse, mutect2, varscan2
- ALG13 | c.3294G>A p.W1098* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99322446; called by muse, mutect2, varscan2
- ALK | c.3971C>A p.S1324Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202169, COSV66565498; called by muse, mutect2, varscan2
- ALK | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV101200890; called by muse, mutect2, varscan2
- ALOX5AP | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1456113725, COSV100996296, COSV100996297; called by muse, mutect2, varscan2
- ALPK3 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200846317; called by muse, mutect2, varscan2
- ALS2 | c.2171-1G>T p.X724_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99969445; called by muse, mutect2, varscan2
- AMDHD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758223660, COSV57137813; called by muse, mutect2, varscan2
- AMELX | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100498349; called by muse, varscan2
- AMER1 | c.2566A>C p.S856R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100366345; called by mutect2, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2, varscan2
- AMFR | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs1468147261, COSV51922933, COSV99316009; called by muse, mutect2, varscan2
- AMFR | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99316011; called by muse, varscan2
- AMIGO2 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as COSV56974663, COSV99873639; called by muse, mutect2, varscan2
- AMN1 | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99861559; called by muse, mutect2, varscan2
- AMOT | c.1717G>A p.E573K (on ENST00000371959 / NM_001113490.1; = p.E164K on NM_133265.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs767625475, COSV59060609; called by muse, mutect2, varscan2
- AMPD1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs149424604, COSV100814939; called by muse, mutect2, varscan2
- AMPD1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV62420055; called by muse, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, mutect2, varscan2
- AMY2B | c.1152A>C p.E384D | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100796160; called by muse, mutect2, varscan2
- ANAPC4 | c.1365T>G p.H455Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100194106; called by muse, mutect2, varscan2
- ANGPT1 | c.572dup p.N191Kfs*7 | Frame Shift Ins (INS) | VAF 32/71 reads (45%) | catalogued as rs777650478, COSV104399203; called by mutect2, varscan2
- ANGPT1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs573252778; called by muse, mutect2, varscan2
- ANGPT2 | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV100290977; called by muse, mutect2, varscan2
- ANGPTL3 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99224820; called by muse, mutect2, varscan2
- ANGPTL5 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV100527836; called by muse, mutect2, varscan2
- ANGPTL6 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); catalogued as COSV99463745; called by muse, mutect2, varscan2
- ANK2 | c.7338C>A p.N2446K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV100002123; called by muse, mutect2, varscan2
- ANKIB1 | c.364A>C p.K122Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99729245; called by muse, mutect2, varscan2
- ANKMY2 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100186835; called by muse, mutect2, varscan2
- ANKRD11 | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs369218399; called by muse, mutect2, varscan2
- ANKRD11 | c.4038G>T p.E1346D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99969702; called by muse, mutect2, varscan2
- ANKRD12 | c.1847T>G p.F616C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.41); catalogued as COSV100040948; called by muse, mutect2, varscan2
- ANKRD12 | c.3747T>G p.F1249L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV100041498; called by muse, mutect2, varscan2
- ANKRD12 | c.5011C>T p.H1671Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1420638357, COSV100041504; called by muse, mutect2
- ANKRD13C | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99257143; called by mutect2, varscan2
- ANKRD23 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100450457; called by muse, mutect2, varscan2
- ANKRD29 | c.288A>C p.R96S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV99409204; called by muse, mutect2, varscan2
- ANKRD30A | c.805C>A p.Q269K (on ENST00000611781; = p.Q213K on NM_052997.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.803); catalogued as rs1435688063, COSV100653701, COSV100654274; called by muse, mutect2, varscan2
- ANKRD30A | c.2131G>T p.D711Y (on ENST00000611781; = p.D655Y on NM_052997.2) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100653703; called by muse, mutect2, varscan2
- ANKRD30A | c.3392A>C p.K1131T (on ENST00000611781; = p.K1075T on NM_052997.2) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100653704; called by muse, mutect2, varscan2
- ANKRD34B | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV58614539; called by muse, mutect2, varscan2
- ANKRD35 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100841756; called by muse, mutect2
- ANKRD35 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100841714; called by muse, mutect2, varscan2
- ANKRD49 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs767511021, COSV57060117; called by muse, mutect2
- ANKRD52 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV99921388; called by muse, mutect2, varscan2
- ANKS1A | c.911-1G>T p.X304_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100832532, COSV64462094; called by muse, mutect2
- ANKS4B | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100289863; called by muse, mutect2, varscan2
- ANO1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV60285547; called by muse, varscan2
- ANO3 | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV56790495, COSV56807883; called by muse, mutect2
- ANO4 | c.332A>G p.Y111C (on ENST00000392977 / NM_001286615.2; = p.Y76C on NM_178826.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1324414033, COSV100153061; called by muse, mutect2, varscan2
- ANO4 | c.1529T>C p.F510S (on ENST00000392977 / NM_001286615.2; = p.F475S on NM_178826.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100153062; called by muse, varscan2
- ANOS1 | c.837A>C p.K279N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99390987; called by muse, mutect2, varscan2
- ANPEP | c.981C>A p.F327L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100263163, COSV55591667; called by muse, mutect2, varscan2
- ANTXR2 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100226625; called by muse, mutect2, varscan2
- ANXA3 | c.315C>T p.G105= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as rs746083634, COSV53715832; called by muse, mutect2, varscan2
- AOC2 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53199204, COSV99513668; called by muse, mutect2, varscan2
- AOX1 | c.828A>T p.K276N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1312571666, COSV101022041, COSV65983575; called by muse, mutect2, varscan2
- AP1G1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs768433108, COSV55486253, COSV55496649; called by muse, mutect2, varscan2
- AP1G2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV58115734; called by muse, mutect2, varscan2
- AP1S1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99973055; called by muse, mutect2, varscan2
- AP1S3 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100525270, COSV57511693; called by muse, mutect2, varscan2
- AP3B1 | c.11A>C p.N4T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV99671711; called by muse, mutect2, varscan2
- APBA1 | c.2445T>G p.I815M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99596349; called by muse, mutect2, varscan2
- APBB1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs1196883346, COSV100194128, COSV54978965; called by muse, mutect2, varscan2
- APBB1IP | c.1313C>A p.S438Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.897); catalogued as COSV100882104; called by muse, mutect2, varscan2
- APC | c.425C>A p.S142* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57356100, COSV57372170; called by muse, mutect2
- APC | c.2483C>A p.T828N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as CD011081, COSV99968288; called by muse, mutect2, varscan2
- APC | c.4463T>G p.L1488* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as CM095526, COSV57322122, COSV57323073, COSV57360736; called by muse, mutect2, varscan2
- APLP1 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs765081638, COSV99697732; called by muse, mutect2, varscan2
- APLP2 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV53840148; called by muse, mutect2, varscan2
- APOB | c.9304T>G p.F3102V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV99266088; called by muse, mutect2, varscan2
- APOBEC3A | c.474T>G p.F158L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.37); catalogued as COSV99970346; called by muse, mutect2, varscan2
- APOBEC3D | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99328988; called by muse, mutect2, varscan2
- APOBR | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100112403, COSV60491876; called by muse, mutect2, varscan2
- APOD | c.108T>G p.N36K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV100581212; called by muse, mutect2, varscan2
- APOH | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs751154716, COSV52773441; called by muse, mutect2, varscan2
- APTX | c.823A>C p.N275H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV100541384; called by muse, mutect2, varscan2
- AQR | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV99334105; called by muse, mutect2, varscan2
- AR | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218564193, CX116061, COSV65958933; called by muse, mutect2, varscan2
- ARAP2 | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100394791; called by muse, mutect2, varscan2
- ARAP2 | c.1805A>C p.K602T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100394792; called by muse, mutect2
- ARAP2 | c.1649G>T p.R550I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs187371781; called by muse, mutect2, varscan2
- ARFGAP3 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99605345; called by muse, mutect2, varscan2
- ARHGAP11B | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | catalogued as COSV101451800; called by muse, mutect2, varscan2
- ARHGAP20 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs200417489; called by muse, mutect2, varscan2
- ARHGAP30 | c.2455G>T p.D819Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV100920297, COSV63519745; called by muse, mutect2, varscan2
- ARHGAP31 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as rs201216830, COSV99957243; called by muse, mutect2, varscan2
- ARHGAP35 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs765847154, COSV101351202; called by muse, mutect2, varscan2
- ARHGAP5 | c.1186A>C p.N396H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV100565465; called by muse, mutect2, varscan2
- ARHGAP5 | c.1977C>A p.F659L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100565469; called by muse, mutect2, varscan2
- ARHGAP6 | c.872A>G p.D291G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100273045; called by muse, mutect2, varscan2
- ARHGAP9 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs374553966; called by muse, mutect2, varscan2
- ARHGEF10L | c.993C>A p.Y331* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV99393065; called by muse, mutect2, varscan2
- ARHGEF11 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100810193, COSV63816030; called by muse, mutect2, varscan2
- ARHGEF15 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs534121147, COSV62724325, COSV62725188; called by muse, mutect2, varscan2
- ARHGEF18 | c.1703C>T p.A568V (on ENST00000359920 / NM_001130955.2; = p.A464V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100149616; called by muse, mutect2, varscan2
- ARHGEF26 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100726598; called by mutect2, varscan2
- ARHGEF28 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs772380154, COSV55270901; called by muse, mutect2, varscan2
- ARHGEF28 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs373253212; called by muse, mutect2, varscan2
- ARHGEF3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99575465; called by muse, mutect2
- ARHGEF40 | c.1346A>C p.K449T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100070432; called by muse, mutect2, varscan2
- ARHGEF7 | c.753A>C p.K251N (on ENST00000375741 / NM_001113511.2; = p.K73N on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99521682; called by muse, mutect2, varscan2
- ARID4A | c.1533G>T p.E511D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV62166868; called by muse, mutect2, varscan2
- ARID4A | c.3049C>T p.R1017* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as rs1344759651, COSV62162823; called by muse, mutect2, varscan2
- ARID4A | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100794356; called by muse, mutect2, varscan2
- ARID4B | c.3551C>A p.S1184Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99935764; called by muse, mutect2, varscan2
- ARID4B | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751191473, COSV99935766; called by muse, mutect2, varscan2
- ARID4B | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV51613820; called by muse, mutect2, varscan2
- ARID5B | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV54422989; called by muse, mutect2, varscan2
- ARMC3 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs1377941927, COSV99958319; called by muse, mutect2, varscan2
- ARMC8 | c.1202G>A p.R401Q (on ENST00000469044 / NM_001363941.2; = p.R387Q on NM_015396.6) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as rs181951568, COSV100509677; called by muse, mutect2, varscan2
- ARMC8 | c.1453C>T p.R485* (on ENST00000469044 / NM_001363941.2; = p.R471* on NM_015396.6) | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100509679; called by muse, varscan2
- ARMCX5-GPRASP2 | c.614T>G p.I205S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV100771925; called by muse, mutect2, varscan2
- ARMH3 | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as COSV100898968; called by muse, mutect2, varscan2
- ARMH4 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99958388; called by muse, mutect2, varscan2
- ARNTL | c.1250G>A p.R417Q (on ENST00000403290 / NM_001297719.2; = p.R416Q on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV100724630, COSV100724725, COSV100724755; called by muse, mutect2, varscan2
- ARSK | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as COSV66170448; called by muse, mutect2, varscan2
- AS3MT | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as COSV100185554, COSV54916460; called by mutect2, varscan2
- ASAP1 | c.1369T>A p.C457S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100727384; called by muse, mutect2, varscan2
- ASB13 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs757058806, COSV63092204; called by muse, mutect2, varscan2
- ASB5 | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV99641777; called by muse, mutect2, varscan2
- ASCL1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99902043; called by muse, mutect2, varscan2
- ASF1B | c.52T>G p.F18V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99654315; called by muse, mutect2
- ASL | c.802T>G p.F268V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100508912; called by muse, mutect2, varscan2
- ASPM | c.3331G>T p.E1111* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99660558; called by mutect2, varscan2
- ASPM | c.804A>C p.K268N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as CD142041, COSV99660561; called by muse, mutect2, varscan2
- ASTE1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs773437504, COSV53909044; called by muse, mutect2, varscan2
- ASTL | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.058); catalogued as rs760745469, COSV100668372; called by muse, mutect2, varscan2
- ASXL1 | c.3506C>A p.S1169Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1212204313, COSV60103582, COSV60121036; called by muse, mutect2, varscan2
- ASXL1 | c.3809G>T p.R1270I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100039705; called by muse, mutect2, varscan2
- ASXL3 | c.2567C>A p.A856D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1413319712, COSV99325251; called by muse, varscan2
- ASXL3 | c.3642G>T p.E1214D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.053); catalogued as COSV99325254; called by muse, mutect2, varscan2
- ASXL3 | c.4811G>T p.S1604I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV99325256; called by muse, mutect2, varscan2
- ASXL3 | c.5802G>T p.M1934I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV52467917, COSV99325257; called by muse, mutect2, varscan2
- ATAD2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99784824; called by muse, mutect2, varscan2
- ATAD2 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs558571857, COSV54880415, COSV99784425; called by muse, mutect2, varscan2
- ATAD2 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV99784827; called by muse, mutect2, varscan2
- ATAD5 | c.5002G>T p.E1668* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100430018; called by muse, varscan2
- ATAD5 | c.5023A>G p.N1675D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100430020; called by muse, varscan2
- ATF6 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1010112292, COSV100909282; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs760001414, COSV63405877; called by muse, varscan2
- ATG16L1 | c.1447C>T p.R483* (on ENST00000392017 / NM_030803.7; = p.R464* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100731192; called by muse, mutect2, varscan2
- ATG4A | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58964421; called by muse, mutect2
- ATG4C | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749357381, COSV58603833, COSV58606729; called by muse, mutect2, varscan2
- ATG4D | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs766736761, COSV100470184; called by muse, mutect2, varscan2
- ATG7 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs748753444, COSV100607406; called by muse, mutect2, varscan2
- ATP10A | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1407076325, COSV100791327; called by muse, mutect2, varscan2
- ATP10A | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1317398516, COSV100791329; called by muse, mutect2, varscan2
- ATP10B | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs201139624, COSV100469476; called by muse, varscan2
- ATP11A | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1417105477, COSV52107059; called by muse, mutect2, varscan2
- ATP11C | c.2539A>T p.N847Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100558091; called by muse, mutect2
- ATP11C | c.2422T>G p.L808V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100558098; called by muse, mutect2, varscan2
- ATP11C | c.1838G>T p.R613I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs776753802, COSV59561860, COSV59563934; called by muse, mutect2, varscan2
- ATP12A | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762399901, COSV54518642; called by muse, mutect2, varscan2
- ATP13A3 | c.3751C>A p.Q1251K (on ENST00000645319 / NM_001367549.1; = p.Q1221K on NM_024524.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.192); catalogued as COSV55467713, COSV99757236; called by muse, mutect2, varscan2
- ATP13A5 | c.3486G>T p.K1162N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99290512; called by muse, mutect2, varscan2
- ATP13A5 | c.1675-1G>A p.X559_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100664814, COSV60869073; called by muse, mutect2, varscan2
- ATP1A1 | c.155A>G p.H52R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV99814558; called by muse, mutect2, varscan2
- ATP23 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs944466017, COSV100274472, COSV55687389; called by muse, mutect2, varscan2
- ATP2B1 | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV99665836, COSV99666093; called by muse, mutect2, varscan2
- ATP2B3 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54847168; called by muse, mutect2, varscan2
- ATP6AP1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1557197509, COSV100870699; called by muse, mutect2, varscan2
- ATP6AP2 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101011432, COSV65797478; called by muse, mutect2, varscan2
- ATP6V0A1 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99231151; called by muse, mutect2, varscan2
- ATP6V1C2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598832, COSV55365148; called by muse, mutect2, varscan2
- ATP6V1G1 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100928699; called by muse, mutect2, varscan2
- ATP7A | c.2600C>A p.S867Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100431019; called by muse, mutect2, varscan2
- ATP8A1 | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100046446; called by mutect2, varscan2
- ATP8A2 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99682424; called by muse, mutect2
- ATP8B4 | c.1061G>T p.S354I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99466007, COSV99466434; called by muse, mutect2, varscan2
- ATP9B | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs199859397, COSV100303706; called by muse, mutect2, varscan2
- ATR | c.7219C>T p.R2407C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746049210, COSV63384106; called by muse, mutect2, varscan2
- ATR | c.2416C>A p.L806I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV63385286; called by mutect2, varscan2
- ATRNL1 | c.3326G>T p.S1109I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100371111; called by muse, mutect2, varscan2
- ATRX | c.6236G>A p.R2079Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64883229; called by muse, mutect2, varscan2
- ATRX | c.5099T>G p.L1700R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100970919; called by muse, mutect2, varscan2
- ATRX | c.4947G>T p.E1649D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100970921; called by muse, mutect2, varscan2
- ATRX | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64871810, COSV64872548; called by muse, mutect2, varscan2
- ATRX | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV64879818; called by muse, mutect2, varscan2
- ATXN2 | c.736C>T p.R246* (on ENST00000550104; = p.R86* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV101112801; called by muse, mutect2
- ATXN2L | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100294549; called by mutect2, varscan2
- ATXN3L | c.568A>C p.K190Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV101019427; called by muse, mutect2, varscan2
- AUH | c.263-1G>T p.X88_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100342510; called by muse, mutect2, varscan2
- AXDND1 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100858470; called by muse, mutect2, varscan2
- AXL | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99996700; called by muse, mutect2, varscan2
- AZGP1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1388978064, COSV99447998; called by muse, mutect2, varscan2
- B3GALT1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs759629237, COSV59908708; called by muse, mutect2, varscan2
- B3GAT1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs749052528, COSV56995458; called by mutect2, varscan2
- B3GLCT | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as COSV58456078; called by muse, mutect2, varscan2
- B3GLCT | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs770760169, COSV58456618; called by muse, mutect2, varscan2
- BAAT | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99408535; called by muse, mutect2, varscan2
- BAHCC1 | c.6005C>T p.S2002F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as rs1178991621, COSV100311733; called by muse, mutect2
- BAIAP2 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100348292; called by muse, mutect2, varscan2
- BAIAP3 | c.3024G>T p.Q1008H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV50104426, COSV99136270; called by muse, mutect2, varscan2
- BANK1 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs773468425, COSV100536461; called by muse, mutect2, varscan2
- BARHL2 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100966060; called by muse, mutect2
- BAZ1B | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs782668908, COSV100289846; called by muse, mutect2, varscan2
- BBS10 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99675167; called by muse, mutect2
- BBS4 | c.26G>T p.R9I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV51437174; called by muse, mutect2, varscan2
- BBX | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs770138977, COSV57878573; called by muse, mutect2, varscan2
- BCAP31 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1557047458, COSV100798946; called by muse, varscan2
- BCAR1 | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV99366807; called by muse, mutect2, varscan2
- BCAR3 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99550859, COSV99551066; called by muse, mutect2, varscan2
- BCAR3 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99550860; called by muse, mutect2, varscan2
- BCHE | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100012650; called by muse, mutect2, varscan2
- BCL11B | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV61734277; called by muse, mutect2, varscan2
- BCL9 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV99325298; called by muse, mutect2, varscan2
- BCL9 | c.2148G>T p.M716I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99325306; called by muse, mutect2, varscan2
- BCL9 | c.4213A>G p.M1405V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.176); catalogued as COSV99325308; called by muse, mutect2, varscan2
- BCLAF1 | c.2629A>C p.N877H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs757553274, COSV99219611; called by muse, mutect2, varscan2
- BCOR | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1048287551, COSV60709520; called by muse, mutect2, varscan2
- BCORL1 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.025); catalogued as COSV99499841; called by muse, mutect2, varscan2
- BCORL1 | c.4733A>C p.N1578T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99499846; called by muse, mutect2
- BDKRB1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as rs773048836, COSV99387905; called by muse, mutect2, varscan2
- BDKRB2 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs769027698, COSV60013752; called by muse, mutect2, varscan2
- BDP1 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV100703211; called by muse, mutect2, varscan2
- BEX5 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100375058; called by muse, mutect2, varscan2
- BFAR | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99902288; called by muse, mutect2, varscan2
- BFSP1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763099974, COSV64900602; called by muse, mutect2, varscan2
- BICDL2 | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV99560655; called by muse, mutect2, varscan2
- BIRC6 | c.12103G>T p.D4035Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV101134344; called by muse, mutect2
- BIVM-ERCC5 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99958813; called by muse, mutect2, varscan2
- BMP10 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV99770429; called by muse, mutect2, varscan2
- BMPR1B | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV52783564; called by muse, mutect2, varscan2
- BNIP5 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV101465134; called by muse, mutect2, varscan2
- BOD1L1 | c.2735C>A p.S912Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99239609; called by muse, mutect2, varscan2
- BPIFB3 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100972363; called by muse, mutect2, varscan2
- BPIFB4 | c.1740G>T p.M580I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.437); catalogued as COSV100971551; called by muse, mutect2, varscan2
- BPIFB6 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as rs79809934, COSV62755422, COSV62757447; called by muse, mutect2, varscan2
- BPTF | c.2533G>T p.E845* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100075160; called by muse, mutect2
- BRCA1 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs41286300, CM024206, COSV58798327; ClinVar: likely benign / benign / conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9339T>G p.I3113M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101204328; called by muse, mutect2, varscan2
- BRD3 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs141557823; called by muse, mutect2, varscan2
- BRD4 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99650889; called by muse, mutect2, varscan2
- BRD8 | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV50154806; called by muse, mutect2, varscan2
- BRDT | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.749); catalogued as COSV100746431, COSV100746587; called by muse, mutect2, varscan2
- BRINP2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs778753983, COSV64180016; called by muse, mutect2, varscan2
- BRINP3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs765103774, COSV66523080; called by muse, varscan2
- BRINP3 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV100818969; called by muse, varscan2
- BRWD3 | c.4070C>A p.S1357Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.198); catalogued as COSV100956182; called by muse, varscan2
- BRWD3 | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as rs755874512, COSV64754231; called by muse, mutect2, varscan2
- BRWD3 | c.410A>T p.Y137F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV100956184; called by muse, mutect2, varscan2
- BST1 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.651); catalogued as COSV99399999; called by muse, mutect2, varscan2
- BTAF1 | c.1870T>G p.L624V | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99795456; called by muse, mutect2, varscan2
- BTN1A1 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55069448, COSV99764432; called by muse, mutect2, varscan2
- BTN3A2 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV100709669; called by muse, mutect2, varscan2
- BTNL8 | c.1018A>G p.K340E | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99180490; called by muse, mutect2, varscan2
- BUB1 | c.2556C>A p.F852L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV100241346; called by muse, mutect2, varscan2
- BUB1 | c.1485A>C p.Q495H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100241349; called by muse, mutect2, varscan2
- C12orf50 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100072295; called by muse, mutect2, varscan2
- C12orf50 | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV100072296; called by muse, mutect2, varscan2
- C14orf28 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs1202601891, COSV100290224; called by muse, mutect2, varscan2
- C14orf39 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100407194, COSV58780117; called by muse, mutect2, varscan2
- C14orf39 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV100407728; called by muse, mutect2, varscan2
- C16orf71 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs746265671, COSV54788064; called by muse, mutect2, varscan2
- C17orf100 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99854568; called by muse, mutect2, varscan2
- C17orf97 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376965621, COSV100789310; called by muse, mutect2, varscan2
- C18orf54 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs760888628, COSV100266275; called by muse, mutect2, varscan2
- C19orf44 | c.125A>T p.K42I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99522224; called by muse, mutect2, varscan2
- C1GALT1C1 | c.52T>G p.F18V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100485620; called by muse, mutect2
- C1S | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as rs143180187; called by muse, mutect2, varscan2
- C1orf131 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100009822, COSV59643105; called by muse, mutect2, varscan2
- C1orf141 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63992007; called by muse, mutect2, varscan2
- C1orf210 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756081725, COSV101382214; called by muse, mutect2, varscan2
- C1orf54 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs782598834, COSV100961810; called by muse, mutect2
- C20orf194 | c.1692C>A p.F564L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV99330438, COSV99330875; called by muse, mutect2, varscan2
- C20orf194 | c.1241T>C p.L414S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99330877; called by muse, varscan2
- C20orf96 | c.783G>T p.K261N (on ENST00000360321 / NM_153269.3; = p.K260N on NM_080571.1) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV100826729; called by muse, mutect2
- C2CD5 | c.2702G>A p.R901Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100448828; called by muse, mutect2, varscan2
- C2CD5 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs775622262, COSV61723649; called by muse, mutect2, varscan2
- C2CD6 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99633372; called by muse, mutect2, varscan2
- C2CD6 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV53799937; called by muse, mutect2, varscan2
- C2orf16 | c.2820G>T p.Q940H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100820833; called by muse, mutect2, varscan2
- C3 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs756642830, COSV99836795; called by muse, mutect2, varscan2
- C3 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55572450, COSV99836796; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C4orf17 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99910973; called by muse, mutect2, varscan2
- C5 | c.4364T>G p.I1455S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99798092; called by muse, mutect2, varscan2
- C5 | c.4202G>A p.R1401H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs62578420, COSV99798096; called by muse, mutect2, varscan2
- C5orf38 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs779809202, COSV57409721; called by muse, mutect2, varscan2
- C6orf15 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV52538374; called by muse, mutect2, varscan2
- C6orf89 | c.392G>T p.R131I (on ENST00000373685; = p.R138I on NM_152734.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.372); catalogued as COSV100769733; called by mutect2, varscan2
- C8B | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs955479183, COSV100980703, COSV64777175; called by muse, mutect2, varscan2
- C9orf135 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs372154813; called by muse, mutect2, varscan2
- CA5B | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100590748; called by muse, mutect2, varscan2
- CA5B | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100590742; called by muse, mutect2, varscan2
- CACNA1D | c.3046G>A p.G1016S (on ENST00000350061 / NM_001128840.3; = p.G1036S on NM_000720.4) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs749033002, COSV55471762; called by muse, mutect2, varscan2
- CACNA1E | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs1558147711, COSV100703224; called by muse, mutect2, varscan2
- CACNA1F | c.2119-1G>T p.X707_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV59903674, COSV59903990; called by muse, mutect2, varscan2
- CACNA1F | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100544988; called by muse, mutect2, varscan2
- CACNA1H | c.1266C>A p.F422L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100672910; called by muse, mutect2, varscan2
- CACNA1H | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169352200, COSV61991076; called by muse, mutect2, varscan2
- CACNA1H | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758601422, COSV100671886, COSV62000629; called by muse, mutect2, varscan2
- CACNA1I | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs370082731; called by muse, mutect2, varscan2
- CACNA1I | c.3468G>T p.E1156D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100360586; called by muse, mutect2, varscan2
- CACNA1S | c.2483G>T p.R828I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100754986, COSV62939128; called by muse, mutect2, varscan2
- CACNA2D1 | c.3178T>G p.F1060V (on ENST00000356253 / NM_001366867.1; = p.F1048V on NM_000722.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100666782; called by muse, mutect2, varscan2
- CACNA2D1 | c.2863C>A p.L955I (on ENST00000356253 / NM_001366867.1; = p.L943I on NM_000722.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV62381154; called by mutect2, varscan2
- CACNA2D1 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs1554398166, COSV100666783, COSV100667330; called by muse, mutect2, varscan2
- CACNA2D2 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.941); catalogued as COSV56568095; called by muse, mutect2, varscan2
- CACNA2D3 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758120700, COSV55518521; called by muse, varscan2
- CACNB1 | c.1102A>G p.N368D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100703443; called by muse, mutect2, varscan2
- CACNB2 | c.484C>T p.R162* (on ENST00000324631 / NM_201596.3; = p.R107* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs1257625518, COSV56640971; called by muse, mutect2, varscan2
- CACNB4 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99138486; called by muse, mutect2, varscan2
- CACNG3 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV99136469; called by muse, mutect2, varscan2
- CAD | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1417632852, COSV53025229; called by muse, mutect2, varscan2
- CALB1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374432228; called by muse, mutect2, varscan2
- CALCOCO2 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99363818; called by muse, mutect2, varscan2
- CALCR | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV100810595; called by muse, mutect2, varscan2
- CALD1 | c.1417G>T p.E473* (on ENST00000361675 / NM_033138.4; = p.E218* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV62647166; called by muse, mutect2, varscan2
- CALHM5 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV100635610; called by muse, mutect2
- CALR3 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as COSV99522223; called by muse, mutect2, varscan2
- CAMK1G | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs147371769; called by muse, mutect2, varscan2
- CAMK2B | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.199); catalogued as rs1421929860, COSV99323079, COSV99323140; called by mutect2, varscan2
- CAMK4 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV99999568; called by muse, mutect2, varscan2
- CAMSAP3 | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs767636770, COSV99350999; called by muse, mutect2, varscan2
- CAND2 | c.2183C>A p.S728Y (on ENST00000456430 / NM_001162499.2; = p.S635Y on NM_012298.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.594); catalogued as COSV55991452, COSV99929305; called by muse, mutect2
- CANT1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as rs372332465; called by muse, mutect2, varscan2
- CAPN5 | c.454G>A p.E152K (on ENST00000456580; = p.E112K on NM_004055.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs782738219, COSV53685788; called by muse, mutect2
- CAPN6 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV100136914; called by muse, mutect2, varscan2
- CAPN7 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99512869; called by muse, mutect2, varscan2
- CAPRIN2 | c.770T>G p.F257C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51830207, COSV99195528; called by muse, mutect2, varscan2
- CAPZA3 | c.705A>T p.K235N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV99856493; called by mutect2, varscan2
- CARD11 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV62717134; called by muse, mutect2, varscan2
- CARF | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as rs758931336, COSV100247704; called by muse, mutect2, varscan2
- CARF | c.1497T>G p.L499= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100247708; called by muse, mutect2, varscan2
- CARMIL3 | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100549651; called by muse, mutect2, varscan2
- CARNMT1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100961747; called by muse, mutect2, varscan2
- CARNMT1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.082); catalogued as rs1389888862, COSV65193036; called by muse, mutect2, varscan2
- CARNS1 | c.1751G>A p.G584D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1403684877, COSV100322054; called by muse, mutect2, varscan2
- CASP1 | c.1016C>A p.S339Y (on ENST00000436863 / NM_033292.4; = p.S318Y on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99507141, COSV99507714; called by muse, mutect2, varscan2
- CASP14 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV55666834, COSV99693063, COSV99693117; called by muse, mutect2, varscan2
- CASP4 | c.8-1G>A p.X3_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as rs200174319, COSV67744775; called by muse, mutect2, varscan2
- CASP5 | c.544-1G>A p.X182_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as rs766107398, COSV99507707; called by muse, mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CASP8 | c.1144G>T p.E382* (on ENST00000432109 / NM_033355.3; = p.E399* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV51850819; called by muse, mutect2, varscan2
- CASP8 | c.1412G>T p.R471I (on ENST00000432109 / NM_033355.3; = p.R488I on NM_001228.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV51856798, COSV51859211; called by muse, mutect2
- CASQ1 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100927312, COSV63624182; called by muse, mutect2, varscan2
- CASS4 | c.2070T>G p.F690L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV100824745; called by muse, varscan2
- CASZ1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs768615741, COSV59736171; called by muse, mutect2, varscan2
- CATIP | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV56821840; called by muse, mutect2, varscan2
- CATSPER2 | c.686T>G p.I229S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV100390798; called by muse, mutect2, varscan2
- CATSPERB | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765894114, COSV56434298; called by muse, mutect2, varscan2
- CATSPERD | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV101062622, COSV67534523; called by muse, mutect2, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by muse, mutect2, varscan2
- CBLB | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99913606; called by muse, mutect2, varscan2
- CBLB | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs567817486, COSV51421767; called by muse, mutect2, varscan2
- CBLL2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257570318, COSV60368932; called by muse, mutect2, varscan2
- CBWD2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99380593; called by muse, mutect2, varscan2
- CC2D2A | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs543650388, COSV67502578; ClinVar: uncertain significance; called by muse, mutect2
- CCDC12 | c.385A>C p.K129Q (on ENST00000425441 / NM_001277074.1; = p.K142Q on NM_144716.5) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV99438967; called by muse, mutect2, varscan2
- CCDC141 | c.2321A>C p.K774T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV99836955; called by muse, mutect2, varscan2
- CCDC151 | c.1744T>G p.L582V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV100710556; called by muse, mutect2, varscan2
- CCDC160 | c.182T>G p.F61C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV100892121; called by muse, mutect2, varscan2
- CCDC170 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.048); catalogued as rs781096492, COSV53343398; called by muse, mutect2, varscan2
- CCDC170 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53338228, COSV53345045; called by muse, mutect2, varscan2
- CCDC181 | c.54C>A p.D18E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100890338; called by muse, varscan2
- CCDC186 | c.1440A>C p.K480N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100991120; called by muse, mutect2, varscan2
- CCDC186 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100991028; called by muse, mutect2, varscan2
- CCDC22 | c.522G>T p.L174F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100879820; called by muse, mutect2, varscan2
- CCDC22 | c.1565A>C p.Q522P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873181; called by muse, mutect2, varscan2
- CCDC27 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs760910706, COSV53898240; called by muse, mutect2, varscan2
- CCDC50 | c.605G>T p.R202I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101165306, COSV101165369; called by muse, mutect2, varscan2
- CCDC51 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99602979; called by muse, mutect2, varscan2
- CCDC58 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs370054189, COSV99360511; called by mutect2, varscan2
- CCDC74A | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV99723765; called by muse, mutect2, varscan2
- CCDC81 | c.1351G>T p.E451* (on ENST00000445632 / NM_001156474.2; = p.E361* on NM_021827.4) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99564438; called by muse, mutect2, varscan2
- CCDC82 | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1362079925, COSV99567381; called by muse, mutect2, varscan2
- CCDC83 | c.718C>A p.H240N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.447); catalogued as COSV54704906, COSV99721765; called by muse, mutect2, varscan2
- CCDC88A | c.2120G>T p.R707L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55071642, COSV99710613; called by mutect2, varscan2
- CCDC89 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100320867; called by muse, mutect2, varscan2
- CCDC89 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100320869; called by muse, mutect2, varscan2
- CCDC96 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59508971; called by muse, mutect2, varscan2
- CCHCR1 | c.483A>C p.E161D | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100883888; called by muse, mutect2, varscan2
- CCKAR | c.534T>G p.I178M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55160953; called by muse, mutect2, varscan2
- CCL5 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs779249457; called by muse, mutect2, varscan2
- CCN4 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99137146; called by mutect2, varscan2
- CCNA1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs746799158, COSV55221107; called by muse, mutect2, varscan2
- CCNB3 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0.234); catalogued as COSV52071307, COSV99329240; called by muse, mutect2, varscan2
- CCNE1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.21); catalogued as COSV99388473; called by muse, mutect2, varscan2
- CCNY | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs779630924, COSV99590674; called by muse, mutect2, varscan2
- CCP110 | c.1210A>C p.K404Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs893945078, COSV101195293; called by muse, mutect2, varscan2
- CCPG1 | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51244019; called by muse, mutect2
- CCSER1 | c.1475G>T p.R492I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100392800; called by muse, mutect2, varscan2
- CCT4 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101075236; called by muse, mutect2, varscan2
- CCT6B | c.1132G>T p.G378* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100030720; called by mutect2, varscan2
- CCT6B | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100030723; called by muse, mutect2
- CD109 | c.738A>C p.L246F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV54646987, COSV99753817; called by mutect2, varscan2
- CD109 | c.3739G>A p.A1247T | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs750803840, COSV54647024, COSV54658058; called by muse, mutect2, varscan2
- CD163 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765869382, COSV63136320; called by muse, mutect2, varscan2
- CD163L1 | c.370C>A p.L124I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as rs780539397, COSV100550187; called by muse, mutect2, varscan2
- CD180 | c.1440C>A p.H480Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99842283; called by muse, mutect2, varscan2
- CD1A | c.326-1G>T p.X109_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV56860114, COSV99192433; called by muse, mutect2, varscan2
- CD2 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.199); catalogued as COSV101040145; called by muse, mutect2, varscan2
- CD207 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs781853111, COSV69652957; called by muse, mutect2, varscan2
- CD22 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99323325; called by muse, mutect2
- CD226 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV99711217; called by muse, varscan2
- CD226 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs1358404350, COSV54610640; called by muse, mutect2, varscan2
- CD247 | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100758385, COSV100758394; called by muse, mutect2, varscan2
- CD248 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs939652881, COSV100256628; called by muse, mutect2, varscan2
- CD300E | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100151334; called by muse, mutect2, varscan2
- CD34 | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV100178452, COSV60412560; called by muse, mutect2, varscan2
- CD40LG | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV101033496, COSV65698519; called by muse, mutect2, varscan2
- CD68 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs751175406, COSV99548999; called by muse, mutect2, varscan2
- CD81 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144435973; called by muse, mutect2, varscan2
- CDC14B | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs144589840; called by muse, mutect2, varscan2
- CDC20B | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV57050383; called by muse, mutect2, varscan2
- CDC20B | c.394A>C p.I132L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99697011; called by muse, mutect2, varscan2
- CDC42BPA | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100505627, COSV62010781; called by muse, mutect2, varscan2
- CDC45 | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99596790; called by muse, mutect2, varscan2
- CDC5L | c.2277A>C p.E759D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV101015066; called by muse, mutect2, varscan2
- CDC7 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375702482, COSV52309241, COSV99319834; called by muse, mutect2, varscan2
- CDC73 | c.908-1G>T p.X303_splice | Splice Site (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100813895; called by muse, mutect2, varscan2
- CDH10 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, mutect2, varscan2
- CDH10 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52581798; called by muse, varscan2
- CDH10 | c.1964T>C p.V655A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100051869; called by muse, varscan2
- CDH10 | c.1394-2A>C p.X465_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100051871; called by muse, mutect2, varscan2
- CDH10 | c.1152T>G p.F384L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100051875; called by muse, mutect2, varscan2
- CDH10 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV100051544, COSV52581723; called by muse, mutect2
- CDH11 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1398193552, COSV51768263, COSV99218747; called by muse, mutect2, varscan2
- CDH13 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs370399855, COSV51860138; called by muse, mutect2, varscan2
- CDH13 | c.2137C>A p.L713M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51815672; called by muse, mutect2, varscan2
- CDH7 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100542572; called by muse, mutect2
- CDH7 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.734); catalogued as rs765560942, COSV59890129; called by muse, mutect2, varscan2
- CDH8 | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100182124; called by muse, mutect2, varscan2
- CDH8 | c.1045A>C p.K349Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100182125; called by muse, mutect2, varscan2
- CDHR2 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771752055, COSV56136251; called by muse, mutect2, varscan2
- CDHR2 | c.3871G>A p.A1291T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs749523542, COSV56137105; called by muse, mutect2, varscan2
- CDK16 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770772825, COSV52093104; called by muse, mutect2, varscan2
- CDK6 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs373488172, COSV56008836; called by muse, mutect2
- CDK7 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56512884; called by muse, mutect2
- CDR1 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV100983424, COSV65164149; called by muse, mutect2, varscan2
- CDT1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs570140833, COSV56347520; called by muse, varscan2
- CDYL | c.700G>A p.E234K (on ENST00000328908 / NM_001368125.1; = p.E180K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs141221618; called by mutect2, varscan2
- CEACAM16 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200295094; called by muse, mutect2, varscan2
- CEACAM6 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.841); catalogued as rs1392952384, COSV99555604; called by muse, mutect2, varscan2
- CEACAM7 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs782307166, COSV50072489; called by muse, mutect2, varscan2
- CEACAM7 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99137252; called by muse, mutect2, varscan2
- CECR2 | c.877C>T p.R293C (on ENST00000342247 / NM_001290047.2; = p.R130C on NM_001290046.1) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV52837399; called by muse, mutect2, varscan2
- CELA1 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1293644579, COSV99530139; called by mutect2, varscan2
- CELF3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778026308, COSV51881488; called by mutect2, varscan2
- CEMIP | c.1133A>G p.K378R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV99586846; called by muse, mutect2, varscan2
- CEMIP2 | c.241A>C p.N81H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100987410; called by muse, mutect2, varscan2
- CENPE | c.5870T>C p.I1957T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99478202; called by muse, mutect2, varscan2
- CENPE | c.4584T>G p.I1528M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99478204; called by muse, mutect2, varscan2
- CENPF | c.4361G>T p.R1454I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV65273849; called by muse, mutect2, varscan2
- CENPI | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV54501126, COSV99515434; called by muse, mutect2, varscan2
- CENPQ | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100225783; called by muse, mutect2, varscan2
- CENPU | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99859711, COSV99859983; called by muse, mutect2, varscan2
- CEP112 | c.2764G>T p.E922* (on ENST00000392769 / NM_001353127.1; = p.E178* on NM_001037325.3) | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100439258; called by muse, mutect2, varscan2
- CEP112 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67138329; called by muse, mutect2, varscan2
- CEP112 | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV101210798, COSV67145299; called by muse, mutect2, varscan2
- CEP128 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99825010; called by muse, mutect2, varscan2
- CEP152 | c.3639G>T p.E1213D (on ENST00000380950 / NM_001194998.2; = p.E1157D on NM_014985.4) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100358891; called by muse, mutect2, varscan2
- CEP290 | c.5777G>A p.R1926Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs778030031, CM111853, COSV58351378; called by muse, mutect2, varscan2
- CEP290 | c.4510G>T p.E1504* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100468421, COSV100468943; called by muse, mutect2, varscan2
- CEP350 | c.2918T>C p.I973T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100854853; called by muse, mutect2, varscan2
- CEP57L1 | c.1193C>A p.S398* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100425871; called by muse, mutect2, varscan2
- CEP70 | c.1687T>G p.F563V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99389282; called by muse, mutect2, varscan2
- CEP70 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1224097376, COSV99389285; called by muse, mutect2, varscan2
- CEP83 | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100352920, COSV60411885; called by muse, mutect2, varscan2
- CEP85 | c.2274C>A p.N758K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99432432; called by muse, mutect2, varscan2
- CEP85L | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.584); catalogued as COSV100821256; called by muse, mutect2, varscan2
- CES1 | c.1246C>A p.L416M (on ENST00000361503 / NM_001025194.2; = p.L415M on NM_001266.5) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.729); catalogued as COSV100828699, COSV62088600; called by muse, mutect2, varscan2
- CES1 | c.904-1G>T p.X302_splice | Splice Site (SNP) | VAF 28/114 reads (25%) | catalogued as rs140353865, COSV62086187, COSV62090788; called by muse, mutect2, varscan2
- CES5A | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99307662; called by muse, mutect2, varscan2
- CFAP100 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369057465, COSV100729110; called by muse, mutect2, varscan2
- CFAP206 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as rs377042908; called by muse, mutect2, varscan2
- CFAP251 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs759115110, COSV56608100; called by muse, mutect2, varscan2
- CFAP251 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs766268774, COSV56613191; called by muse, mutect2, varscan2
- CFAP47 | c.4448A>C p.K1483T | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.291); catalogued as COSV100545444; called by muse, mutect2, varscan2
- CFAP52 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100235297; called by muse, varscan2
- CFAP54 | c.5005G>T p.D1669Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100733231, COSV100733429; called by muse, mutect2
- CFAP57 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs776508053, COSV63016695; called by muse, mutect2, varscan2
- CFAP61 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as COSV99845309; called by muse, mutect2, varscan2
- CFAP61 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55632536, COSV99845313; called by muse, mutect2, varscan2
- CFAP65 | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs769450768, COSV58559131; called by muse, mutect2, varscan2
- CFAP65 | c.3473+1G>A p.X1158_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as rs577732313, COSV100445289; called by muse, mutect2, varscan2
- CFAP70 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772771453, COSV100160644, COSV60281927; called by mutect2, varscan2
- CFAP91 | c.444-1G>T p.X148_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99847189; called by muse, mutect2, varscan2
- CFAP91 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99847191; called by muse, mutect2, varscan2
- CFH | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs766043678, CM1512040, COSV62777879; called by mutect2, varscan2
- CFHR2 | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.615); catalogued as COSV100804341; called by muse, mutect2, varscan2
- CFTR | c.1470C>A p.F490L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.365); catalogued as CD962511, COSV50043400, COSV99136895; called by muse, mutect2, varscan2
- CGREF1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV99565213; called by muse, mutect2, varscan2
- CHAT | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1451392375, COSV100340285; called by muse, mutect2, varscan2
- CHAT | c.1926C>A p.F642L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60324835; called by muse, mutect2, varscan2
- CHCHD1 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100863398; called by muse, mutect2, varscan2
- CHCHD2 | c.444C>T p.N148= | Splice Region (SNP) | VAF 10/22 reads (45%) | catalogued as rs758536733, COSV68169866; called by muse, mutect2, varscan2
- CHD3 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as rs1426104891, COSV100390760, COSV100391300; called by muse, mutect2, varscan2
- CHD7 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV101418282; called by muse, mutect2, varscan2
- CHD9 | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373076192; called by muse, mutect2, varscan2
- CHIT1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262669492, COSV99705353; called by muse, mutect2, varscan2
- CHL1 | c.1115A>G p.D372G (on ENST00000397491 / NM_001253387.1; = p.D388G on NM_006614.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99851468; called by muse, mutect2, varscan2
- CHL1 | c.1326C>A p.F442L (on ENST00000397491 / NM_001253387.1; = p.F458L on NM_006614.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV56603660, COSV99851470; called by muse, mutect2, varscan2
- CHM | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100753392; called by muse, mutect2, varscan2
- CHM | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100753395; called by muse, mutect2, varscan2
- CHORDC1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776330399, COSV57705173; called by muse, mutect2, varscan2
- CHP2 | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270184; called by muse, mutect2, varscan2
- CHRM2 | c.1196C>A p.T399N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281453; called by muse, mutect2, varscan2
- CHRNA4 | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100937433; called by muse, mutect2, varscan2
- CHRNB1 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV99548221, COSV99548361; called by muse, mutect2, varscan2
- CHRNB3 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs760632906, COSV99251269; called by muse, mutect2, varscan2
- CHRNB4 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV99929403; called by muse, mutect2, varscan2
- CHRND | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV51317544, COSV51332839; called by muse, mutect2, varscan2
- CHRND | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51320927, COSV99285889; called by muse, mutect2
- CHST13 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60043162; called by muse, mutect2, varscan2
- CHST2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV100535989; called by muse, mutect2, varscan2
- CIART | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV99290318; called by muse, mutect2, varscan2
- CILK1 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100607795; called by muse, mutect2, varscan2
- CILP | c.2581C>T p.R861W | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780257557, COSV99973533; called by muse, mutect2, varscan2
- CILP2 | c.1334G>T p.R445I | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99364646; called by muse, mutect2, varscan2
- CILP2 | c.3396G>T p.E1132D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV99364810; called by muse, mutect2, varscan2
- CIP2A | c.1927C>A p.L643I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842964; called by muse, mutect2, varscan2
- CIR1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1340786357, COSV59595568; called by muse, mutect2, varscan2
- CKAP5 | c.5347G>A p.D1783N (on ENST00000529230 / NM_001008938.4; = p.D1723N on NM_014756.3) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.075); catalogued as rs781759452, COSV56369790; called by muse, mutect2, varscan2
- CKAP5 | c.5197C>A p.L1733I (on ENST00000529230 / NM_001008938.4; = p.L1673I on NM_014756.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV100370899, COSV56364399; called by muse, mutect2
- CKM | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1340153316, COSV99035629; called by muse, mutect2, varscan2
- CKMT1B | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765473721, COSV55852482; called by muse, mutect2, varscan2
- CLASP2 | c.3563C>A p.S1188Y (on ENST00000359576; = p.S1187Y on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV100222944, COSV100223620, COSV56278595; called by muse, mutect2, varscan2
- CLBA1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1476760233, COSV101121064; called by muse, mutect2, varscan2
- CLCA1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99322505; called by muse, mutect2
- CLCA1 | c.1655A>G p.Y552C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV99322506; called by muse, varscan2
- CLCA2 | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV100991576, COSV65287111; called by muse, mutect2, varscan2
- CLCN5 | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100260228; called by muse, mutect2, varscan2
- CLDN10 | c.464+1G>T p.X155_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as rs755231416, COSV100176178; called by muse, mutect2, varscan2
- CLDN14 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs532176130, COSV100578758; called by muse, mutect2, varscan2
- CLEC10A | c.770C>T p.A257V (on ENST00000254868 / NM_182906.4; = p.A233V on NM_006344.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs770259937, COSV54700461; called by muse, mutect2, varscan2
- CLEC12A | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); catalogued as rs533589131, COSV100429535; called by muse, mutect2, varscan2
- CLINT1 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV99754213; called by muse, varscan2
- CLIP4 | c.1561A>C p.K521Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100192003; called by muse, mutect2, varscan2
- CLNK | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99905319; called by muse, mutect2, varscan2
- CLSPN | c.3941C>A p.S1314Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1458417721, COSV52050471; called by muse, mutect2, varscan2
- CLSTN2 | c.1674+2T>C p.X558_splice | Splice Site (SNP) | VAF 5/9 reads (56%) | catalogued as COSV101515802; called by muse, mutect2, varscan2
- CLTCL1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs375568935; called by muse, mutect2, varscan2
- CLTRN | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs772800840, COSV100982206; called by muse, mutect2, varscan2
- CMSS1 | c.582C>T p.V194= | Splice Region (SNP) | VAF 14/26 reads (54%) | catalogued as COSV70440400; called by muse, mutect2, varscan2
- CMTM5 | c.620A>C p.K207T (on ENST00000339180 / NM_001288746.2; = p.K140T on NM_138460.3) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV100198071; called by muse, mutect2
- CMTM7 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs780296829, COSV100569964; called by muse, mutect2, varscan2
- CNBD1 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs1458783591, COSV101582242; called by muse, mutect2, varscan2
- CNBD2 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100839115; called by muse, mutect2
- CNDP2 | c.54C>A p.Y18* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100159150; called by muse, mutect2, varscan2
- CNGA2 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100323759; called by muse, mutect2, varscan2
- CNGB1 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51900886; called by muse, mutect2, varscan2
- CNNM1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1050256791, COSV100763895; called by muse, mutect2, varscan2
- CNOT1 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.321); catalogued as rs776606248, COSV100409476; called by muse, mutect2, varscan2
- CNOT10 | c.1019A>C p.K340T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV100094598; called by muse, mutect2, varscan2
- CNOT3 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs775550862, COSV55362727; called by muse, mutect2, varscan2
4,746 further variants in this file (3,594 protein-altering or splice-affecting, 1,025 silent, 127 other) are not listed here.
